Somatic mutation profile of tumor specimen HCM-CSHL-0372-C25-01A (aliquot HCM-CSHL-0372-C25-01A-11D-A79M-36) from HCMI case HCM-CSHL-0372-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.2 years (25,632 days).
Specimen HCM-CSHL-0372-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d8ca019-11cd-4236-aebc-b6a3f2978c17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0372-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0372-C25-11A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2f6c372-a69c-4b8d-8141-007f608e9f06

The open-access MAF lists 63 somatic variants for this specimen: 39 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 22, Nonsense Mutation 5, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 145/663 reads (22%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 117/326 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 79/361 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 68/229 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV61683964, COSV61688596, COSV61694890; called by muse, mutect2, varscan2
- ADAMTS17 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 194/702 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs781074609; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 128/356 reads (36%) | catalogued as rs758608743; called by mutect2, varscan2
- BCAS4 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 189/484 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs111566476; called by muse, mutect2, varscan2
- BCL11A | c.1888G>A p.A630T (on ENST00000335712 / NM_001365609.1; = p.A664T on NM_018014.4) | Missense Mutation (SNP) | VAF 135/572 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100185319, COSV59632438; called by muse, mutect2, varscan2
- CFHR4 | c.1525C>A p.P509T (on ENST00000367416 / NM_001201551.2; = p.P263T on NM_006684.5) | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756854486; called by muse, mutect2, varscan2
- DCHS1 | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 144/611 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs139750490; called by muse, mutect2, varscan2
- FICD | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 145/523 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs756414496; called by muse, mutect2, varscan2
- FMN2 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 152/664 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1253960201; called by muse, mutect2, varscan2
- IGF2BP1 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV51735379; called by muse, mutect2, varscan2
- KRTAP12-2 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 168/734 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.324); catalogued as rs369113881; called by muse, mutect2, varscan2
- MECOM | c.2249G>A p.R750Q (on ENST00000468789 / NM_001105078.4; = p.R938Q on NM_004991.4) | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52961254; called by muse, mutect2, varscan2
- MMP28 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 146/564 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761787539; called by muse, mutect2, varscan2
- MUC16 | c.16829G>A p.R5610Q | Missense Mutation (SNP) | VAF 97/388 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.199); catalogued as rs761072024, COSV67470593; called by muse, mutect2, varscan2
- NEK4 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs559285627, COSV51782461; called by muse, mutect2, varscan2
- NSL1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 64/349 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.899); catalogued as COSV65327788; called by muse, mutect2, varscan2
- NUB1 | c.1660G>A p.G554R (on ENST00000568733 / NM_001243351.1; = p.G540R on NM_016118.4) | Missense Mutation (SNP) | VAF 148/565 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs375777780; called by muse, mutect2, varscan2
- OTOG | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 144/583 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs767006121, COSV100695326; called by muse, mutect2
- PCDHB4 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 80/348 reads (23%) | catalogued as rs946920377; called by muse, mutect2, varscan2
- PHACTR1 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 101/425 reads (24%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs760163672, COSV60678565; called by muse, mutect2, varscan2
- PTPRS | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 105/419 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs778260386, COSV53609048; called by muse, mutect2, varscan2
- RNF43 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 124/523 reads (24%) | catalogued as COSV68460881; called by muse, mutect2, varscan2
- TAOK3 | c.161_163del p.K54del | In Frame Del (DEL) | VAF 44/179 reads (25%) | catalogued as rs765520762; called by pindel, varscan2
- TMEM185B | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 142/483 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs918389334; called by muse, mutect2, varscan2
- WAS | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 253/871 reads (29%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as rs782666797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD29 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCAR2 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 127/466 reads (27%) | called by muse, mutect2, varscan2
- CCDC82 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 107/402 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CLEC1B | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EXT2 | c.153G>T p.E51D (on ENST00000343631; = p.E84D on NM_000401.3) | Missense Mutation (SNP) | VAF 98/396 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by mutect2, varscan2
- FFAR2 | c.620T>A p.L207H | Missense Mutation (SNP) | VAF 128/497 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HELZ2 | c.6154G>A p.D2052N (on ENST00000467148 / NM_001037335.2; = p.D1483N on NM_033405.3) | Missense Mutation (SNP) | VAF 303/683 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MAP3K4 | c.1734G>T p.W578C | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS15A | c.131_133+1del p.X44_splice | Splice Site (DEL) | VAF 68/285 reads (24%) | called by mutect2, pindel, varscan2
- SGO1 | c.1004dup p.Y335* | Nonsense Mutation (INS) | VAF 78/328 reads (24%) | called by mutect2, pindel, varscan2
- YLPM1 | c.2300G>A p.R767K | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ACRV1 | c.243C>T p.A81= | Silent (SNP) | VAF 113/436 reads (26%) | catalogued as rs141232180; called by muse, mutect2, varscan2
- ALDH4A1 | c.516C>T p.F172= | Silent (SNP) | VAF 172/471 reads (37%) | catalogued as rs1553154020; called by muse, mutect2, varscan2
- APAF1 | c.1410G>A p.P470= (on ENST00000551964 / NM_181861.2; = p.P459= on NM_001160.3) | Silent (SNP) | VAF 83/316 reads (26%) | catalogued as rs1205113196, COSV59665189, COSV59665422; called by muse, mutect2, varscan2
- BARHL1 | c.774G>A p.P258= | Silent (SNP) | VAF 170/515 reads (33%) | catalogued as rs922543244, COSV99707566; called by muse, mutect2, varscan2
- BHLHE40 | c.396G>A p.G132= | Silent (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- CACNA1H | c.423C>T p.A141= | Silent (SNP) | VAF 99/391 reads (25%) | catalogued as rs769394588; called by muse, mutect2, varscan2
- CACNA2D3 | c.54C>T p.L18= | Silent (SNP) | VAF 109/470 reads (23%) | called by muse, mutect2, varscan2
- CFAP47 | c.6654G>A p.T2218= | Silent (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- EPCAM | c.18C>G p.V6= | Silent (SNP) | VAF 128/501 reads (26%) | called by muse, mutect2, varscan2
- FMO3 | c.1029C>A p.I343= | Silent (SNP) | VAF 78/396 reads (20%) | called by muse, mutect2, varscan2
- HSPA1A | c.1746C>T p.D582= | Silent (SNP) | VAF 178/801 reads (22%) | catalogued as rs771552351; called by muse, mutect2, varscan2
- HUWE1 | c.7380C>T p.D2460= | Silent (SNP) | VAF 129/546 reads (24%) | catalogued as COSV53335590; called by muse, mutect2, varscan2
- IQUB | c.1515T>C p.I505= | Silent (SNP) | VAF 93/372 reads (25%) | called by muse, mutect2, varscan2
- ITIH2 | c.834C>T p.D278= | Silent (SNP) | VAF 75/342 reads (22%) | catalogued as rs763511313; called by muse, mutect2, varscan2
- KIF23 | c.1872G>A p.K624= | Silent (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2, varscan2
- NUBP2 | c.483G>A p.T161= | Silent (SNP) | VAF 123/484 reads (25%) | catalogued as rs145452816; called by muse, mutect2, varscan2
- PCDHA10 | c.1968G>A p.P656= | Silent (SNP) | VAF 169/566 reads (30%) | catalogued as COSV56515075; called by muse, mutect2, varscan2
- PHF8 | c.1449C>T p.N483= (on ENST00000357988 / NM_001184896.1; = p.N447= on NM_015107.3) | Silent (SNP) | VAF 91/381 reads (24%) | catalogued as COSV100153793; called by muse, mutect2, varscan2
- RTL1 | c.2517C>T p.S839= | Silent (SNP) | VAF 161/536 reads (30%) | called by muse, mutect2
- SCN11A | c.726C>T p.I242= | Silent (SNP) | VAF 68/271 reads (25%) | catalogued as rs771737794, COSV56573163; called by muse, mutect2, varscan2
- SOX1 | c.474C>T p.G158= | Silent (SNP) | VAF 107/351 reads (30%) | called by muse, mutect2, varscan2
- TM2D2 | c.447C>T p.Y149= (on ENST00000456397 / NM_078473.3; = p.Y106= on NM_031940.4) | Silent (SNP) | VAF 45/234 reads (19%) | called by muse, mutect2, varscan2
- FOXO1 | c.*118_*119insC | 3'UTR (INS) | VAF 71/296 reads (24%) | catalogued as rs943801669; called by mutect2, pindel, varscan2
- NRG1 | chr8:31640051 G>A | 5'Flank (SNP) | VAF 18/416 reads (4%) | catalogued as rs1390495162; called by muse, mutect2
